Somatic mutation profile of tumor specimen ALCH-ADJ3-TTP1-A (aliquot ALCH-ADJ3-TTP1-A-1-0-D-A565-36) from ALCHEMIST case ALCH-ADJ3, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 65.4 years (23,873 days).
Specimen ALCH-ADJ3-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 98a2d7c5-be7f-4847-9bca-911cb452e8c0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ADJ3-NB1-A (Blood Derived Normal), aliquot ALCH-ADJ3-NB1-A-2-1-D-A565-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4684df5b-d60e-4a2b-b543-16d0ce36d4b3

The open-access MAF lists 54 somatic variants for this specimen: 34 protein-altering or splice-affecting, 14 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 14, 5'UTR 2, 3'UTR 2, Intron 1, In Frame Del 1, Frame Shift Del 1, Nonsense Mutation 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2235_2249del p.E746_A750del | In Frame Del (DEL) | VAF 164/1153 reads (14%) | hotspot (GDC flag); catalogued as rs121913421, COSV51765119; ClinVar: drug response; called by mutect2, pindel, varscan2
- PKLR | c.1291G>A p.A431T | Missense Mutation (SNP) | VAF 66/460 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.642); catalogued as rs762591322, CM981573, COSV100712843; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.473G>T p.R158L | Missense Mutation (SNP) | VAF 77/353 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs587782144, CM102353, CM165595, CM994513, COSV52676395, COSV52678258, COSV52680378, COSV53545833; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COL8A2 | c.910C>T p.R304W | Missense Mutation (SNP) | VAF 73/450 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.83); catalogued as rs773088842, COSV100291338; called by muse, mutect2, varscan2
- EPAS1 | c.611A>G p.N204S | Missense Mutation (SNP) | VAF 120/1140 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs770514486; called by muse, mutect2, varscan2
- FAT1 | c.10720G>A p.V3574M | Missense Mutation (SNP) | VAF 85/388 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.882); catalogued as rs767643023, COSV71674715; called by muse, mutect2, varscan2
- FFAR4 | c.133A>G p.T45A | Missense Mutation (SNP) | VAF 14/366 reads (4%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs1392555266; called by muse, mutect2
- KANK3 | c.1028C>A p.A343E | Missense Mutation (SNP) | VAF 7/113 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs1307204170; called by muse, mutect2
- MPO | c.241C>T p.R81W | Missense Mutation (SNP) | VAF 129/860 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs771107623, COSV56569130; called by muse, mutect2, varscan2
- RGS18 | c.603G>T p.L201F | Missense Mutation (SNP) | VAF 68/542 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV66509882; called by muse, mutect2, varscan2
- SOHLH2 | c.667C>T p.Q223* | Nonsense Mutation (SNP) | VAF 21/121 reads (17%) | catalogued as COSV65901970; called by muse, mutect2, varscan2
- SRRM5 | c.1628G>C p.R543T | Missense Mutation (SNP) | VAF 66/743 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.131); catalogued as rs1209311664; called by muse, mutect2
- TRIM17 | c.725G>A p.R242Q | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs779700937; called by muse, mutect2, varscan2
- UGT2A3 | c.694G>C p.E232Q | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99280311; called by mutect2, varscan2
- ANGPT1 | c.400C>A p.L134I | Missense Mutation (SNP) | VAF 17/249 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.831); called by muse, mutect2
- CEP135 | c.2575A>G p.I859V | Missense Mutation (SNP) | VAF 142/734 reads (19%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CLEC7A | c.704T>C p.V235A (on ENST00000304084 / NM_197947.3; = p.V189A on NM_022570.5) | Missense Mutation (SNP) | VAF 60/448 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- COPS5 | c.511G>A p.D171N | Missense Mutation (SNP) | VAF 17/343 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- DACT1 | c.2380C>G p.Q794E | Missense Mutation (SNP) | VAF 111/587 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- DSC3 | c.2358C>G p.N786K | Missense Mutation (SNP) | VAF 122/638 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- EVPLL | c.317G>T p.R106L | Missense Mutation (SNP) | VAF 34/414 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.038); called by muse, mutect2
- GPR101 | c.1286C>A p.T429N | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- HERC1 | c.12331T>A p.Y4111N | Missense Mutation (SNP) | VAF 62/656 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.013); called by muse, mutect2
- IGHV3-48 | c.187G>A p.G63R | Missense Mutation (SNP) | VAF 18/529 reads (3%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.764); called by muse, mutect2
- LORICRIN | c.935A>C p.K312T | Missense Mutation (SNP) | VAF 104/603 reads (17%) | PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NPM1 | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 64/413 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- OR2V2 | c.591G>T p.E197D | Missense Mutation (SNP) | VAF 27/608 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.02); called by muse, mutect2
- SERPINA6 | c.1102C>A p.L368I | Missense Mutation (SNP) | VAF 82/490 reads (17%) | SIFT tolerated (0.92); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SOX13 | c.365A>G p.D122G | Missense Mutation (SNP) | VAF 25/582 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2
- SPATA31A1 | c.1483G>A p.A495T | Missense Mutation (SNP) | VAF 33/1442 reads (2%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.618); called by muse, mutect2
- SPOCK3 | c.621G>C p.R207S | Missense Mutation (SNP) | VAF 91/363 reads (25%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TLR8 | c.913G>T p.A305S (on ENST00000218032 / NM_138636.5; = p.A323S on NM_016610.4) | Missense Mutation (SNP) | VAF 53/173 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TSPOAP1 | c.3158G>T p.R1053L | Missense Mutation (SNP) | VAF 121/768 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- ZCRB1 | c.302_324del p.Y101* | Frame Shift Del (DEL) | VAF 35/309 reads (11%) | called by mutect2, pindel
- ACTN3 | c.1824C>T p.T608= | Silent (SNP) | VAF 24/159 reads (15%) | catalogued as rs1252587983; called by muse, mutect2, varscan2
- AFTPH | c.2025G>A p.L675= | Silent (SNP) | VAF 58/281 reads (21%) | catalogued as COSV53219289; called by muse, mutect2, varscan2
- BAG6 | c.3312C>T p.L1104= (on ENST00000676571; = p.L1057= on NM_080702.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 31/174 reads (18%) | called by muse, mutect2, varscan2
- CLTCL1 | c.3186C>T p.S1062= | Silent (SNP) | VAF 22/442 reads (5%) | catalogued as rs374972988; called by muse, mutect2
- COL22A1 | c.1149G>A p.A383= | Silent (SNP) | VAF 42/672 reads (6%) | catalogued as rs746255639, COSV57326795, COSV57356565; called by muse, mutect2
- EFNA4 | c.285G>A p.K95= | Silent (SNP) | VAF 33/420 reads (8%) | called by muse, mutect2
- FBN1 | c.2319T>C p.S773= | Silent (SNP) | VAF 72/526 reads (14%) | catalogued as rs1478632942; called by muse, mutect2, varscan2
- KREMEN2 | c.1362C>T p.S454= | Silent (SNP) | VAF 69/279 reads (25%) | catalogued as rs1220870418; called by muse, mutect2, varscan2
- PABPC5 | c.210G>A p.A70= | Silent (SNP) | VAF 20/267 reads (7%) | catalogued as rs747339331, COSV57039349; called by muse, mutect2
- PCDHA11 | c.1317G>A p.R439= | Silent (SNP) | VAF 22/523 reads (4%) | catalogued as rs371557347; called by muse, mutect2
- PDXDC1 | c.102A>G p.T34= | Silent (SNP) | VAF 84/641 reads (13%) | called by muse, mutect2, varscan2
- SERPINA6 | c.1101C>A p.T367= | Silent (SNP) | VAF 81/484 reads (17%) | called by muse, mutect2, varscan2
- SLC10A2 | c.333C>A p.A111= | Silent (SNP) | VAF 42/398 reads (11%) | called by muse, mutect2, varscan2
- ZNF648 | c.852C>T p.C284= | Silent (SNP) | VAF 13/251 reads (5%) | catalogued as rs922766588; called by muse, mutect2
- CASP16P | chr16:3149799 C>T | 3'Flank (SNP) | VAF 33/130 reads (25%) | called by muse, mutect2, varscan2
- CCN6 | c.-7C>A | 5'UTR (SNP) | VAF 167/966 reads (17%) | called by muse, mutect2, varscan2
- PEX19 | c.*1638C>T | 3'UTR (SNP) | VAF 26/747 reads (3%) | called by muse, mutect2
- RNF126 | c.*177G>T | 3'UTR (SNP) | VAF 4/24 reads (17%) | called by muse, mutect2
- SF3B4 | c.-23G>C | 5'UTR (SNP) | VAF 12/334 reads (4%) | called by muse, mutect2
- TRIP12 | c.99-875T>C | Intron (SNP) | VAF 47/273 reads (17%) | called by muse, mutect2, varscan2
